Somatic mutation profile of tumor specimen TCGA-17-Z010-01A (aliquot TCGA-17-Z010-01A-01W-0746-08) from TCGA case TCGA-17-Z010, project TCGA-LUAD (Lung Adenocarcinoma).
Specimen TCGA-17-Z010-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5a0f7171-ee07-4a43-b7a5-60f14584ffe1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-17-Z010-11A (Solid Tissue Normal), aliquot TCGA-17-Z010-11A-01W-0746-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bc8d0e74-296a-4e60-becd-fc5b67e2d0b6

The open-access MAF lists 308 somatic variants for this specimen: 222 protein-altering or splice-affecting, 78 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 183, Silent 78, Nonsense Mutation 18, Frame Shift Del 10, Splice Site 6, Frame Shift Ins 5, RNA 3, Intron 2, 3'UTR 2, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CLCN5 | c.1399C>T p.R467* | Nonsense Mutation (SNP) | VAF 55/232 reads (24%) | catalogued as rs797044811, CM052173; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 12/36 reads (33%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AKAP6 | c.3403C>T p.R1135* | Nonsense Mutation (SNP) | VAF 18/200 reads (9%) | catalogued as COSV55209080; called by muse, mutect2
- ALDH4A1 | c.1465G>A p.V489I | Missense Mutation (SNP) | VAF 18/108 reads (17%) | SIFT tolerated (0.61); PolyPhen benign (0.009); catalogued as rs150916561; called by muse, mutect2
- AMOTL1 | c.2833G>C p.E945Q | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.806); catalogued as COSV100504203; called by muse, mutect2
- AP002512.3 | c.1173G>T p.M391I | Missense Mutation (SNP) | VAF 11/86 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.03); catalogued as COSV54405369, COSV54408841; called by muse, mutect2, varscan2
- APEX2 | c.293G>T p.G98V | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1220954839; called by muse, mutect2, varscan2
- ATR | c.1372C>A p.Q458K | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT tolerated, low confidence (0.98); PolyPhen benign (0); catalogued as COSV99052466; called by muse, mutect2, varscan2
- BMPR1B | c.76C>T p.R26C | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.005); catalogued as rs758706811, COSV52775245, COSV52780828; called by muse, mutect2, varscan2
- BOC | c.833G>T p.R278L | Missense Mutation (SNP) | VAF 27/117 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0.228); catalogued as COSV56347140; called by muse, mutect2, varscan2
- BRINP3 | c.1548C>A p.S516R | Missense Mutation (SNP) | VAF 29/147 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV66521759; called by muse, mutect2, varscan2
- C20orf85 | c.402G>T p.Q134H | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV100959472; called by muse, mutect2
- C7 | c.1022G>T p.G341V | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.23); PolyPhen benign (0.099); catalogued as rs1429403751; called by muse, mutect2, varscan2
- CABS1 | c.629C>A p.S210Y | Missense Mutation (SNP) | VAF 27/111 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV56734529; called by muse, mutect2, varscan2
- CCNB3 | c.1243A>T p.M415L | Missense Mutation (SNP) | VAF 34/107 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV52080263; called by muse, mutect2, varscan2
- CFH | c.1813G>C p.G605R | Missense Mutation (SNP) | VAF 14/107 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100809258; called by muse, mutect2, varscan2
- CLGN | c.1192G>A p.E398K | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.889); catalogued as rs564584207, COSV57774139; called by muse, mutect2, varscan2
- CMTR2 | c.1495G>T p.G499* | Nonsense Mutation (SNP) | VAF 36/98 reads (37%) | catalogued as COSV100578925; called by muse, mutect2, varscan2
- COL11A1 | c.3574G>T p.G1192* | Nonsense Mutation (SNP) | VAF 14/75 reads (19%) | catalogued as COSV62188987; called by muse, mutect2, varscan2
- CSMD3 | c.522G>T p.Q174H | Missense Mutation (SNP) | VAF 25/63 reads (40%) | SIFT tolerated (0.12); PolyPhen benign (0.178); catalogued as COSV52107799; called by muse, mutect2, varscan2
- DHX38 | c.1630A>G p.I544V | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.027); catalogued as rs1373088700; called by muse, mutect2, varscan2
- DISP3 | c.1340G>T p.G447V | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53823339, COSV99037586; called by muse, mutect2, varscan2
- DNAH5 | c.8261G>T p.G2754V | Missense Mutation (SNP) | VAF 10/85 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.908); catalogued as rs546101625; called by muse, mutect2, varscan2
- DRD5 | c.485G>T p.G162V | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.645); catalogued as rs1215258931; called by muse, mutect2, varscan2
- DYRK3 | c.938G>A p.R313H | Missense Mutation (SNP) | VAF 9/184 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs17851298; called by muse, mutect2
- FANCM | c.2704G>C p.D902H | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.541); catalogued as COSV57499219; called by muse, mutect2, varscan2
- FANCM | c.3469G>A p.E1157K | Missense Mutation (SNP) | VAF 15/81 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs374461604; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FAT3 | c.733G>T p.G245* | Nonsense Mutation (SNP) | VAF 50/273 reads (18%) | catalogued as COSV53167604; called by muse, mutect2, varscan2
- FBN3 | c.7930G>T p.G2644W | Missense Mutation (SNP) | VAF 34/95 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs140397273; called by muse, mutect2, varscan2
- FBXL6 | c.986A>G p.Q329R | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT tolerated (0.23); PolyPhen benign (0.024); catalogued as rs782317106; called by muse, mutect2
- FER1L6 | c.3347C>A p.T1116K | Missense Mutation (SNP) | VAF 74/175 reads (42%) | SIFT tolerated (0.94); PolyPhen benign (0.003); catalogued as rs1269327883; called by muse, mutect2, varscan2
- GCDH | c.244C>T p.R82C | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as rs1333480915, COSV53434825; called by muse, mutect2, varscan2
- GHR | c.193T>C p.S65P | Missense Mutation (SNP) | VAF 45/201 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.989); catalogued as CM074887; called by muse, mutect2, varscan2
- GMEB1 | c.771G>C p.L257F | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.637); catalogued as COSV99603436; called by muse, mutect2
- GMPS | c.1584C>A p.Y528* | Nonsense Mutation (SNP) | VAF 28/152 reads (18%) | catalogued as COSV55811898; called by muse, mutect2, varscan2
- GOT1L1 | c.870dup p.N291Qfs*89 | Frame Shift Ins (INS) | VAF 7/33 reads (21%) | catalogued as rs768946390; called by mutect2, varscan2
- GPR12 | c.347C>A p.T116K | Missense Mutation (SNP) | VAF 11/102 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.866); catalogued as COSV67343980; called by muse, mutect2, varscan2
- GPR148 | c.1006C>A p.P336T | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.64); PolyPhen benign (0.003); catalogued as rs1477492732; called by muse, mutect2, varscan2
- GRIK2 | c.938A>T p.D313V | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.596); catalogued as rs757698891; called by muse, mutect2, varscan2
- HGF | c.1301A>C p.K434T | Missense Mutation (SNP) | VAF 15/99 reads (15%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.762); catalogued as COSV55944784, COSV55953381; called by muse, mutect2, varscan2
- HSPA12A | c.952G>A p.G318S | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.575); catalogued as COSV65021473; called by muse, mutect2, varscan2
- HSPA1L | c.970C>T p.R324W | Missense Mutation (SNP) | VAF 5/66 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.894); catalogued as rs779666881, COSV65149091; called by muse, mutect2
- IGSF22 | c.2677C>A p.R893S (on ENST00000319338; = p.R994S on NM_173588.4) | Missense Mutation (SNP) | VAF 12/107 reads (11%) | SIFT tolerated (0.49); PolyPhen benign (0.088); catalogued as COSV55010192; called by muse, mutect2, varscan2
- IMPG2 | c.1657G>T p.V553L | Missense Mutation (SNP) | VAF 53/242 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.006); catalogued as COSV99515358; called by muse, mutect2, varscan2
- ITIH6 | c.2636C>A p.P879H | Missense Mutation (SNP) | VAF 27/175 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.536); catalogued as rs751250816, COSV54495992; called by muse, mutect2, varscan2
- KCNH8 | c.1724G>T p.G575V | Missense Mutation (SNP) | VAF 18/102 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60459510; called by muse, mutect2, varscan2
- KRTAP5-5 | c.632C>A p.S211Y | Missense Mutation (SNP) | VAF 14/132 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.69); catalogued as COSV101294215; called by muse, mutect2, varscan2
- KRTAP9-8 | c.57G>A p.W19* | Nonsense Mutation (SNP) | VAF 74/233 reads (32%) | catalogued as COSV54201134; called by muse, mutect2, varscan2
- MAGEA11 | c.1181C>G p.T394S | Missense Mutation (SNP) | VAF 28/233 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.889); catalogued as COSV60757698; called by muse, mutect2, varscan2
- MAGEC1 | c.504C>G p.S168R | Missense Mutation (SNP) | VAF 44/306 reads (14%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.815); catalogued as COSV53572455; called by muse, mutect2, varscan2
- MAN1B1 | c.316G>T p.D106Y | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.453); catalogued as COSV100814516; called by muse, mutect2
- MASTL | c.1798G>C p.E600Q | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as COSV100668965, COSV60912248; called by muse, mutect2
- MEIS2 | c.1309G>T p.A437S | Missense Mutation (SNP) | VAF 94/316 reads (30%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.074); catalogued as rs374458760; called by muse, mutect2, varscan2
- MEOX2 | c.46G>A p.A16T | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT tolerated (0.12); PolyPhen benign (0.011); catalogued as rs1405769986; called by muse, mutect2, varscan2
- MET | c.3836G>T p.R1279I | Missense Mutation (SNP) | VAF 20/400 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59263314, COSV59268041; called by muse, mutect2
- MMP9 | c.1210G>T p.G404C | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100812298; called by muse, mutect2, varscan2
- MYH15 | c.4747G>C p.E1583Q | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.948); catalogued as COSV56303627; called by muse, mutect2, varscan2
- OR10G7 | c.256C>A p.P86T | Missense Mutation (SNP) | VAF 39/257 reads (15%) | SIFT tolerated (0.56); PolyPhen benign (0.007); catalogued as COSV57868784; called by muse, mutect2, varscan2
- OR10G9 | c.256C>A p.P86T | Missense Mutation (SNP) | VAF 10/85 reads (12%) | SIFT tolerated (0.57); PolyPhen benign (0.011); catalogued as rs1178677113; called by muse, mutect2, varscan2
- OR10H1 | c.436G>T p.G146C | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.722); catalogued as rs1450627724; called by muse, mutect2, varscan2
- OR2B6 | c.122G>T p.G41V | Missense Mutation (SNP) | VAF 35/117 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as rs200272219, COSV99773748; called by muse, mutect2, varscan2
- OR8B12 | c.68G>A p.R23Q | Missense Mutation (SNP) | VAF 7/80 reads (9%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.003); catalogued as rs140680123; called by muse, mutect2, varscan2
- OR8H2 | c.540C>G p.D180E | Missense Mutation (SNP) | VAF 46/229 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs1432984584; called by muse, mutect2, varscan2
- PCCB | c.929C>T p.S310L | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.41); catalogued as COSV52443542; called by muse, mutect2, varscan2
- PCDH10 | c.2563del p.A855Pfs*34 (on ENST00000264360 / NM_032961.3; = p.A855Pfs*24 on NM_020815.3) | Frame Shift Del (DEL) | VAF 5/40 reads (13%) | catalogued as COSV52102642, COSV99994817; called by mutect2, pindel, varscan2
- PCDH11X | c.2945C>A p.S982Y | Missense Mutation (SNP) | VAF 57/147 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53504429; called by muse, mutect2, varscan2
- PGAP4 | c.295del p.R99Gfs*5 | Frame Shift Del (DEL) | VAF 6/37 reads (16%) | catalogued as rs765092936; called by mutect2, pindel, varscan2
- PRMT8 | c.385G>A p.A129T | Missense Mutation (SNP) | VAF 26/89 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.95); catalogued as COSV54219973, COSV99713375; called by muse, mutect2, varscan2
- PTPRG | c.58G>T p.V20L | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); catalogued as rs758281367; called by muse, mutect2
- PXDNL | c.4297C>G p.P1433A | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0.057); catalogued as rs1284510076, COSV62487507; called by muse, varscan2
- RSPH14 | c.863C>A p.A288E | Missense Mutation (SNP) | VAF 14/83 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.863); catalogued as rs756184087, COSV99320749; called by muse, mutect2, varscan2
- RUBCN | c.727G>T p.E243* | Nonsense Mutation (SNP) | VAF 9/43 reads (21%) | catalogued as rs1171332064; called by muse, mutect2, varscan2
- RYR1 | c.5408C>T p.P1803L | Missense Mutation (SNP) | VAF 36/86 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as rs778017724, COSV100615530, COSV62107525; called by muse, mutect2, varscan2
- SAXO1 | c.1354C>T p.Q452* | Nonsense Mutation (SNP) | VAF 13/100 reads (13%) | catalogued as rs750990247, COSV65868678; called by muse, mutect2, varscan2
- SEC31A | c.1457G>T p.R486L | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.084); catalogued as rs747030120, COSV52348040; called by mutect2, varscan2
- SENP7 | c.2302G>C p.E768Q | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as COSV100053970; called by mutect2, varscan2
- SOWAHD | c.898C>T p.Q300* | Nonsense Mutation (SNP) | VAF 7/19 reads (37%) | catalogued as rs1163358743; called by muse, mutect2
- SPTLC2 | c.244A>T p.T82S | Missense Mutation (SNP) | VAF 4/70 reads (6%) | SIFT tolerated (0.17); PolyPhen benign (0.039); catalogued as COSV53642053; called by muse, mutect2
- SYTL5 | c.2093G>T p.G698V | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.558); catalogued as rs756264164, COSV99937241; called by muse, mutect2, varscan2
- TBC1D5 | c.441+1G>A p.X147_splice | Splice Site (SNP) | VAF 36/354 reads (10%) | catalogued as rs1454203436; called by muse, varscan2
- TSHZ3 | c.965A>G p.K322R | Missense Mutation (SNP) | VAF 22/193 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV53673909; called by muse, varscan2
- YIPF4 | c.626G>T p.S209I | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1178009192, COSV53214153; called by muse, mutect2
- ZNF317 | c.1252G>A p.V418M | Missense Mutation (SNP) | VAF 8/100 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.324); catalogued as rs781139661, COSV56108460, COSV56109765; called by muse, mutect2
- ZNF569 | c.288G>C p.L96F | Missense Mutation (SNP) | VAF 6/77 reads (8%) | SIFT tolerated (0.61); PolyPhen benign (0.021); catalogued as COSV99060817; called by muse, mutect2
- ABCB7 | c.1963del p.V655Sfs*30 (on ENST00000373394 / NM_001271696.3; = p.V656Sfs*30 on NM_004299.6) | Frame Shift Del (DEL) | VAF 5/48 reads (10%) | called by mutect2, pindel, varscan2
- ABCF3 | c.475G>T p.A159S | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT tolerated (0.65); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- ABI2 | c.397C>T p.P133S | Missense Mutation (SNP) | VAF 30/124 reads (24%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- ACAD9 | c.1852G>T p.D618Y | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.423); called by muse, mutect2, varscan2
- ACHE | c.1023C>A p.D341E | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated (0.24); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- ADAMTS14 | c.3507G>T p.E1169D | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ADAMTS5 | c.2050-1G>T p.X684_splice | Splice Site (SNP) | VAF 42/154 reads (27%) | called by muse, mutect2, varscan2
- AGTR1 | c.933A>T p.R311S | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- AHNAK | c.14389G>T p.G4797C | Missense Mutation (SNP) | VAF 59/257 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AMER1 | c.2311C>T p.Q771* | Nonsense Mutation (SNP) | VAF 9/55 reads (16%) | called by muse, mutect2, varscan2
- AMHR2 | c.414G>T p.Q138H | Missense Mutation (SNP) | VAF 21/85 reads (25%) | SIFT tolerated (0.17); PolyPhen benign (0.243); called by muse, mutect2, varscan2
- AMPH | c.376G>T p.G126W | Missense Mutation (SNP) | VAF 27/515 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ARFGEF3 | c.2576C>T p.A859V | Missense Mutation (SNP) | VAF 15/97 reads (15%) | SIFT tolerated (0.25); PolyPhen benign (0.007); called by muse, mutect2
- ARHGAP32 | c.3634C>T p.Q1212* (on ENST00000310343 / NM_001378025.1; = p.Q863* on NM_014715.4) | Nonsense Mutation (SNP) | VAF 20/61 reads (33%) | called by muse, mutect2, varscan2
- ARHGAP36 | c.1572G>T p.E524D | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- ARHGEF2 | c.470+1G>T p.X157_splice (on ENST00000361247 / NM_001162383.2; = p.X130_splice on NM_004723.3 and 3 other RefSeq transcripts) | Splice Site (SNP) | VAF 5/92 reads (5%) | called by muse, mutect2
- ARHGEF9 | c.1067G>T p.R356L | Missense Mutation (SNP) | VAF 58/266 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- ATP2B2 | c.3129C>G p.F1043L (on ENST00000352432; = p.F1009L on NM_001683.5) | Missense Mutation (SNP) | VAF 23/182 reads (13%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- BPIFB6 | c.632C>G p.P211R | Missense Mutation (SNP) | VAF 33/259 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- BTNL3 | c.1126G>T p.G376W | Missense Mutation (SNP) | VAF 18/114 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CD163 | c.1583dup p.A531Sfs*13 | Frame Shift Ins (INS) | VAF 25/78 reads (32%) | called by mutect2, pindel, varscan2
- CD177 | c.93T>A p.H31Q | Missense Mutation (SNP) | VAF 32/113 reads (28%) | SIFT tolerated (0.56); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CEMIP2 | c.1432G>T p.G478C | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CHST1 | c.349C>A p.L117I | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CLDN25 | c.659T>A p.L220H | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CLPTM1L | c.869C>T p.T290I | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- COL6A3 | c.5589C>A p.D1863E | Missense Mutation (SNP) | VAF 34/152 reads (22%) | SIFT tolerated (0.6); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DCAF1 | c.2884G>T p.E962* | Nonsense Mutation (SNP) | VAF 33/169 reads (20%) | called by muse, mutect2, varscan2
- DLGAP1 | c.2197G>T p.D733Y | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT tolerated (0.49); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- DNAH3 | c.5611C>A p.L1871M | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- DNAH5 | c.8260G>T p.G2754C | Missense Mutation (SNP) | VAF 9/84 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- DNAH9 | c.10640C>A p.P3547H | Missense Mutation (SNP) | VAF 13/130 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.16); called by muse, mutect2, varscan2
- DOCK2 | c.415G>T p.D139Y | Missense Mutation (SNP) | VAF 12/114 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- DRD5 | c.360C>A p.D120E | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ECE1 | c.2192C>A p.P731H | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- ERBB4 | c.1387A>C p.N463H | Missense Mutation (SNP) | VAF 12/118 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- F2RL2 | c.150G>T p.E50D | Missense Mutation (SNP) | VAF 22/170 reads (13%) | SIFT tolerated (0.61); PolyPhen benign (0); called by muse, mutect2, varscan2
- FAM107B | c.128C>T p.S43F | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.568); called by muse, mutect2, varscan2
- FASTKD2 | c.1498G>T p.D500Y | Missense Mutation (SNP) | VAF 19/113 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- FGD2 | c.541C>A p.R181S | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); called by muse, mutect2, varscan2
- FRAS1 | c.2336G>T p.C779F | Missense Mutation (SNP) | VAF 19/452 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- FRAS1 | c.3542T>C p.V1181A | Missense Mutation (SNP) | VAF 32/194 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- FRMPD1 | c.3568G>T p.G1190W | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.629); called by muse, mutect2, varscan2
- FYB2 | c.1432C>A p.L478I | Missense Mutation (SNP) | VAF 43/223 reads (19%) | SIFT tolerated (0.24); PolyPhen benign (0.271); called by muse, mutect2, varscan2
- GABRA5 | c.106A>T p.S36C | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.353); called by muse, mutect2, varscan2
- GDNF | c.611C>A p.S204Y | Missense Mutation (SNP) | VAF 29/131 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GLI3 | c.3640C>T p.Q1214* | Nonsense Mutation (SNP) | VAF 10/64 reads (16%) | called by muse, mutect2, varscan2
- GPR179 | c.3980C>T p.A1327V (on ENST00000621958; = p.A1326V on NM_001004334.4) | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT tolerated (0.61); PolyPhen benign (0.169); called by muse, mutect2
- GRID2 | c.2170G>C p.E724Q | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.283); called by muse, mutect2, varscan2
- GRM1 | c.3476G>C p.S1159T | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- GZMA | c.371del p.A124Efs*7 | Frame Shift Del (DEL) | VAF 4/37 reads (11%) | called by mutect2, pindel
- HECW1 | c.2801G>T p.R934I | Missense Mutation (SNP) | VAF 10/96 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.261); called by muse, mutect2, varscan2
- HEPH | c.866G>A p.R289H (on ENST00000343002; = p.R22H on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/111 reads (25%) | SIFT tolerated (0.33); PolyPhen benign (0); called by muse, mutect2, varscan2
- HMCN1 | c.15743C>G p.T5248S | Missense Mutation (SNP) | VAF 16/150 reads (11%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- IGKV1-27 | c.313G>C p.V105L | Missense Mutation (SNP) | VAF 31/154 reads (20%) | SIFT tolerated (0.33); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- KCNC1 | c.686A>T p.N229I | Missense Mutation (SNP) | VAF 12/124 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KCNH2 | c.1722G>T p.M574I | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- KDM4A | c.116_117insCT p.H40Ffs*6 | Frame Shift Ins (INS) | VAF 14/88 reads (16%) | called by mutect2, varscan2*
- KDM4A | c.118_119del p.H40Sfs*20 | Frame Shift Del (DEL) | VAF 13/89 reads (15%) | called by mutect2, varscan2*
- KDM7A | c.329A>T p.D110V | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.824); called by muse, mutect2, varscan2
- KIAA1755 | c.442G>T p.E148* | Nonsense Mutation (SNP) | VAF 50/227 reads (22%) | called by muse, mutect2, varscan2
- KRT23 | c.1066G>T p.V356L | Missense Mutation (SNP) | VAF 24/96 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- KRT83 | c.964C>A p.R322S | Missense Mutation (SNP) | VAF 24/145 reads (17%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- KRTAP10-6 | c.968G>T p.C323F | Missense Mutation (SNP) | VAF 26/207 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- KRTAP26-1 | c.445T>A p.L149M | Missense Mutation (SNP) | VAF 66/354 reads (19%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.621); called by muse, varscan2
- LAMA1 | c.8368G>C p.A2790P | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.672); called by muse, mutect2, varscan2
- LAMB2 | c.5156G>A p.R1719H | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated (0.23); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- LARS1 | c.2959A>C p.K987Q (on ENST00000394434 / NM_020117.11; = p.K960Q on NM_016460.3) | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.608); called by muse, mutect2, varscan2
- LARS1 | c.2958G>A p.M986I (on ENST00000394434 / NM_020117.11; = p.M959I on NM_016460.3) | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.05); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- LCE3E | c.241G>T p.G81C | Missense Mutation (SNP) | VAF 37/160 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.713); called by muse, mutect2, varscan2
- LCT | c.4655C>A p.A1552E | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated (0.27); PolyPhen benign (0.083); called by muse, mutect2, varscan2
- LDLRAD3 | c.681C>A p.H227Q | Missense Mutation (SNP) | VAF 31/92 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- LSP1 | c.430G>T p.G144W | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.792); called by mutect2, varscan2
- LYPD6B | c.542C>T p.P181L (on ENST00000409029 / NM_001317004.1; = p.P205L on NM_177964.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 45/271 reads (17%) | SIFT tolerated (0.75); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MAGEA6 | c.445G>A p.V149M | Missense Mutation (SNP) | VAF 19/103 reads (18%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.511); called by muse, mutect2, varscan2
- MARK1 | c.943C>T p.H315Y | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2
- MEGF10 | c.353G>C p.C118S | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- MROH5 | c.1318C>A p.H440N | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.757); called by muse, varscan2
- MRPL1 | c.53A>T p.H18L | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT tolerated (0.24); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MYH3 | c.3118G>A p.E1040K | Missense Mutation (SNP) | VAF 18/101 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.844); called by muse, mutect2, varscan2
- NDUFAF7 | c.217-1G>C p.X73_splice | Splice Site (SNP) | VAF 7/107 reads (7%) | called by muse, mutect2
- NLRP7 | c.640del p.E214Sfs*13 | Frame Shift Del (DEL) | VAF 11/43 reads (26%) | called by mutect2, pindel, varscan2
- OR2AG1 | c.253T>A p.F85I | Missense Mutation (SNP) | VAF 19/112 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- OR2G2 | c.609del p.F203Lfs*9 | Frame Shift Del (DEL) | VAF 12/101 reads (12%) | called by mutect2, pindel, varscan2
- OR2L8 | c.53del p.P18Hfs*18 | Frame Shift Del (DEL) | VAF 29/205 reads (14%) | called by mutect2, pindel, varscan2
- OR5M11 | c.576T>A p.Y192* | Nonsense Mutation (SNP) | VAF 8/88 reads (9%) | called by muse, mutect2
- OR5M11 | c.359A>C p.D120A | Missense Mutation (SNP) | VAF 11/86 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR6C75 | c.341C>A p.A114D | Missense Mutation (SNP) | VAF 9/102 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.912); called by muse, mutect2
- OR8G1 | c.724A>T p.S242C | Missense Mutation (SNP) | VAF 66/248 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.792); called by muse, mutect2, varscan2
- PCDH10 | c.1579G>C p.A527P | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PCDHB10 | c.666G>T p.R222S | Missense Mutation (SNP) | VAF 31/105 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.904); called by muse, mutect2, varscan2
- PCDHGA10 | c.248_250delinsTCGT p.P83Lfs*29 | Frame Shift Ins (INS) | VAF 12/66 reads (18%) | called by pindel, varscan2*
- PCDHGA2 | c.1045A>T p.M349L | Missense Mutation (SNP) | VAF 17/135 reads (13%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); called by muse, mutect2, varscan2
- PCDHGA5 | c.917C>T p.S306L | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.14); called by muse, mutect2, varscan2
- PCDHGB2 | c.631G>T p.V211F | Missense Mutation (SNP) | VAF 17/79 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- PCLO | c.1167G>T p.K389N | Missense Mutation (SNP) | VAF 15/93 reads (16%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- PDE4A | c.2431_2432delinsT p.P811Sfs*162 (on ENST00000380702 / NM_001111307.2; = p.P572Sfs*162 on NM_006202.3) | Frame Shift Del (DEL) | VAF 17/136 reads (13%) | called by pindel, varscan2*
- PGAP1 | c.78G>C p.W26C | Missense Mutation (SNP) | VAF 65/373 reads (17%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- PKHD1L1 | c.2657G>T p.C886F | Missense Mutation (SNP) | VAF 19/252 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.04); called by muse, mutect2
- PPME1 | c.541G>A p.D181N | Missense Mutation (SNP) | VAF 76/274 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PRLR | c.1782C>A p.N594K | Missense Mutation (SNP) | VAF 14/108 reads (13%) | SIFT tolerated (0.23); PolyPhen benign (0); called by muse, mutect2, varscan2
- RAB3GAP2 | c.1130G>T p.R377I | Missense Mutation (SNP) | VAF 49/251 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RAB6D | c.22G>C p.G8R | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.389); called by muse, mutect2, varscan2
- RFX6 | c.2595T>A p.C865* | Nonsense Mutation (SNP) | VAF 10/39 reads (26%) | called by muse, mutect2, varscan2
- RNF157 | c.1755G>T p.Q585H | Missense Mutation (SNP) | VAF 13/112 reads (12%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- RYR2 | c.13021G>T p.E4341* | Nonsense Mutation (SNP) | VAF 15/173 reads (9%) | called by muse, mutect2
- SH3TC1 | c.1113-2A>T p.X371_splice | Splice Site (SNP) | VAF 4/18 reads (22%) | called by muse, mutect2
- SLC7A3 | c.1469C>A p.A490D | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0.05); PolyPhen benign (0.106); called by muse, mutect2
- SLITRK4 | c.1693C>A p.Q565K | Missense Mutation (SNP) | VAF 13/110 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- SMC3 | c.1298A>T p.Q433L | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT tolerated (0.36); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SNTG1 | c.466+2T>A p.X156_splice | Splice Site (SNP) | VAF 7/42 reads (17%) | called by muse, mutect2, varscan2
- SPATA31E1 | c.1259A>G p.Q420R | Missense Mutation (SNP) | VAF 27/134 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.368); called by muse, mutect2, varscan2
- SPEG | c.4364G>T p.S1455I | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.378); called by muse, mutect2, varscan2
- SRRM2 | c.5600G>T p.R1867L | Missense Mutation (SNP) | VAF 18/104 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.756); called by muse, mutect2
- SUMO1 | c.19A>G p.K7E | Missense Mutation (SNP) | VAF 46/174 reads (26%) | SIFT tolerated (0.05); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- SYNE1 | c.124G>T p.A42S | Missense Mutation (SNP) | VAF 19/85 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.913); called by muse, mutect2, varscan2
- TAF1 | c.3743del p.G1248Vfs*6 (on ENST00000373790 / NM_138923.4; = p.G1269Vfs*6 on NM_004606.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 20/136 reads (15%) | called by mutect2, pindel
- TARS2 | c.1524G>T p.W508C | Missense Mutation (SNP) | VAF 18/158 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TFEB | c.1393dup p.R465Pfs*47 | Frame Shift Ins (INS) | VAF 7/36 reads (19%) | called by mutect2, pindel, varscan2
- TLR4 | c.362C>A p.A121D (on ENST00000355622 / NM_138554.5; = p.A81D on NM_003266.4) | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); called by muse, mutect2, varscan2
- TMEM215 | c.679G>T p.G227C | Missense Mutation (SNP) | VAF 17/101 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.642); called by muse, mutect2, varscan2
- TMF1 | c.2053G>T p.A685S | Missense Mutation (SNP) | VAF 15/84 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.099); called by muse, mutect2, varscan2
- TMPRSS11B | c.842C>A p.S281Y | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.797); called by muse, mutect2, varscan2
- TMTC1 | c.1290G>T p.K430N (on ENST00000539277 / NM_001193451.2; = p.K322N on NM_175861.3) | Missense Mutation (SNP) | VAF 27/87 reads (31%) | SIFT tolerated (0.15); PolyPhen benign (0.114); called by muse, mutect2, varscan2
- TPM2 | c.308A>T p.Q103L | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.474); called by muse, mutect2, varscan2
- TRMT13 | c.791G>A p.G264E | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TRO | c.2900C>A p.A967D | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.218); called by muse, mutect2, varscan2
- TTN | c.81690C>A p.N27230K (on ENST00000591111; = p.N19806K on NM_003319.4) | Missense Mutation (SNP) | VAF 42/210 reads (20%) | PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- UGT1A6 | c.434A>T p.D145V | Missense Mutation (SNP) | VAF 36/121 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- UGT2A2 | c.230C>G p.P77R | Missense Mutation (SNP) | VAF 69/274 reads (25%) | SIFT tolerated (0.47); PolyPhen benign (0.147); called by muse, mutect2, varscan2
- USHBP1 | c.824C>A p.T275N | Missense Mutation (SNP) | VAF 31/120 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.216); called by muse, mutect2, varscan2
- VPS13B | c.1958C>T p.S653F | Missense Mutation (SNP) | VAF 22/240 reads (9%) | SIFT tolerated (0.8); PolyPhen benign (0); called by muse, mutect2
- ZAP70 | c.1185C>A p.N395K | Missense Mutation (SNP) | VAF 9/165 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.037); called by muse, mutect2
- ZC3H12B | c.1817C>T p.A606V | Missense Mutation (SNP) | VAF 15/103 reads (15%) | SIFT tolerated (0.27); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZFP37 | c.1003C>A p.H335N | Missense Mutation (SNP) | VAF 13/123 reads (11%) | SIFT tolerated (0.23); PolyPhen benign (0.05); called by muse, mutect2
- ZNF180 | c.1282C>A p.Q428K | Missense Mutation (SNP) | VAF 40/145 reads (28%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- ZNF182 | c.1514A>G p.Q505R | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.118); called by muse, mutect2, varscan2
- ZNF275 | c.919G>C p.E307Q | Missense Mutation (SNP) | VAF 12/98 reads (12%) | SIFT tolerated (0.38); PolyPhen benign (0.177); called by muse, mutect2, varscan2
- ABI3BP | c.1915C>A p.R639= | Silent (SNP) | VAF 17/124 reads (14%) | called by muse, mutect2, varscan2
- ACER1 | c.594G>A p.Q198= | Silent (SNP) | VAF 23/76 reads (30%) | catalogued as rs1412185068, COSV100034123; called by muse, mutect2, varscan2
- ACOT12 | c.405G>T p.V135= | Silent (SNP) | VAF 6/35 reads (17%) | called by muse, mutect2, varscan2
- ACSM5 | c.798C>T p.I266= | Silent (SNP) | VAF 42/317 reads (13%) | called by muse, mutect2, varscan2
- APOBEC2 | c.480G>A p.P160= | Silent (SNP) | VAF 22/125 reads (18%) | catalogued as rs140342245, COSV55143595; called by muse, mutect2, varscan2
- ARHGEF17 | c.3507C>T p.L1169= | Silent (SNP) | VAF 10/33 reads (30%) | called by muse, mutect2, varscan2
- ARHGEF9 | c.1068G>T p.R356= | Silent (SNP) | VAF 59/268 reads (22%) | called by muse, mutect2, varscan2
- ARSH | c.1491T>A p.P497= | Silent (SNP) | VAF 9/56 reads (16%) | called by muse, mutect2, varscan2
- CACNA1C | c.6150C>A p.S2050= (on ENST00000399634 / NM_001167625.1; = p.S1979= on NM_000719.7) | Silent (SNP) | VAF 10/61 reads (16%) | called by muse, mutect2, varscan2
- CLNK | c.1263C>A p.L421= | Silent (SNP) | VAF 4/14 reads (29%) | called by muse, mutect2, varscan2
- COL4A6 | c.2694G>A p.E898= | Silent (SNP) | VAF 7/55 reads (13%) | called by muse, mutect2, varscan2
- COL5A3 | c.4758C>T p.L1586= | Silent (SNP) | VAF 6/27 reads (22%) | called by muse, mutect2
- CPS1 | c.3933C>A p.P1311= | Silent (SNP) | VAF 12/106 reads (11%) | called by muse, mutect2, varscan2
- CRYBB1 | c.351G>A p.E117= | Silent (SNP) | VAF 8/84 reads (10%) | called by muse, mutect2
- DCAF13 | c.906C>T p.F302= | Silent (SNP) | VAF 25/106 reads (24%) | catalogued as rs755314578, COSV52572511; called by muse, mutect2, varscan2
- DDX11 | c.2583A>T p.P861= (on ENST00000545668 / NM_152438.2; = p.Q813L on NM_004399.3) | Silent (SNP) | VAF 15/47 reads (32%) | called by muse, mutect2, varscan2
- DEK | c.615A>G p.K205= | Silent (SNP) | VAF 12/48 reads (25%) | catalogued as rs1561986349; called by muse, mutect2, varscan2
- DGKI | c.633A>C p.A211= | Silent (SNP) | VAF 17/210 reads (8%) | called by muse, mutect2
- ERO1A | c.1080G>A p.E360= | Silent (SNP) | VAF 19/70 reads (27%) | called by muse, mutect2, varscan2
- FAM13C | c.1194G>T p.L398= | Silent (SNP) | VAF 6/46 reads (13%) | called by muse, mutect2, varscan2
- FGD2 | c.540C>A p.P180= | Silent (SNP) | VAF 22/73 reads (30%) | called by muse, mutect2, varscan2
- FSD2 | c.1170C>A p.V390= | Silent (SNP) | VAF 7/38 reads (18%) | catalogued as rs1418739761; called by muse, mutect2, varscan2
- GABRA4 | c.1389T>C p.Y463= | Silent (SNP) | VAF 9/101 reads (9%) | catalogued as rs1391743852; called by muse, mutect2
- GCSAML | c.213C>G p.V71= | Silent (SNP) | VAF 13/177 reads (7%) | called by muse, mutect2
- GRIP2 | c.2157C>A p.A719= (on ENST00000619221; = p.A622= on NM_001080423.4) | Silent (SNP) | VAF 5/29 reads (17%) | catalogued as rs770515703; called by muse, varscan2
- GSG1L | c.696A>T p.A232= (on ENST00000447459 / NM_001109763.2; = p.A77= on NM_144675.2) | Silent (SNP) | VAF 9/57 reads (16%) | called by muse, mutect2, varscan2
- H1-2 | c.540G>A p.A180= | Silent (SNP) | VAF 12/128 reads (9%) | catalogued as rs773564861, COSV59189483, COSV59190009, COSV59190715; called by muse, mutect2
- HEPH | c.2388C>A p.I796= (on ENST00000343002; = p.I529= on NM_014799.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 11/51 reads (22%) | catalogued as COSV57961052; called by muse, mutect2, varscan2
- HEPH | c.2466G>T p.L822= (on ENST00000343002; = p.L555= on NM_014799.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 9/38 reads (24%) | called by muse, mutect2, varscan2
- HOXA3 | c.903C>A p.P301= | Silent (SNP) | VAF 19/37 reads (51%) | catalogued as rs768985843; called by muse, mutect2, varscan2
- HOXD10 | c.480C>A p.T160= | Silent (SNP) | VAF 14/106 reads (13%) | catalogued as rs1198952171, COSV50898771; called by muse, mutect2, varscan2
- HTR5A | c.279C>A p.V93= | Silent (SNP) | VAF 10/24 reads (42%) | catalogued as rs1414728710; called by muse, mutect2, varscan2
- IGHV4-31 | c.120C>A p.T40= | Silent (SNP) | VAF 12/119 reads (10%) | catalogued as rs555147293; called by muse, mutect2, varscan2
- IQGAP3 | c.4791G>T p.L1597= | Silent (SNP) | VAF 7/86 reads (8%) | called by muse, mutect2
- ITSN1 | c.213A>C p.G71= | Silent (SNP) | VAF 16/81 reads (20%) | called by muse, varscan2
- KCNC1 | c.1278C>T p.L426= | Silent (SNP) | VAF 9/81 reads (11%) | catalogued as rs769341904, COSV56396584; called by muse, mutect2, varscan2
- LRRC66 | c.1680C>A p.G560= | Silent (SNP) | VAF 26/196 reads (13%) | catalogued as rs1252077320, COSV100603137; called by muse, mutect2, varscan2
- MAGEL2 | c.3261T>C p.Y1087= | Silent (SNP) | VAF 11/39 reads (28%) | catalogued as rs150927765; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MMP9 | c.1209C>T p.F403= | Silent (SNP) | VAF 19/72 reads (26%) | catalogued as rs1364279397, COSV63433765; called by muse, mutect2, varscan2
- MON2 | c.61T>C p.L21= | Silent (SNP) | VAF 15/98 reads (15%) | called by muse, mutect2, varscan2
- MRGPRX3 | c.618C>A p.S206= | Silent (SNP) | VAF 30/87 reads (34%) | called by muse, mutect2, varscan2
- MRPL35 | c.51A>T p.L17= | Silent (SNP) | VAF 11/76 reads (14%) | called by muse, mutect2, varscan2
- MSL2 | c.447A>T p.S149= | Silent (SNP) | VAF 18/81 reads (22%) | called by muse, mutect2, varscan2
- MTR | c.3387G>A p.L1129= | Silent (SNP) | VAF 20/65 reads (31%) | called by muse, mutect2, varscan2
- MUC16 | c.38958C>A p.T12986= | Silent (SNP) | VAF 42/158 reads (27%) | called by muse, mutect2, varscan2
- MYT1L | c.2436C>A p.G812= | Silent (SNP) | VAF 15/74 reads (20%) | called by muse, mutect2, varscan2
- NEK5 | c.2043G>T p.G681= | Silent (SNP) | VAF 10/72 reads (14%) | catalogued as rs1252980060; called by muse, mutect2, varscan2
- NLRP3 | c.2187G>T p.R729= | Silent (SNP) | VAF 21/193 reads (11%) | called by muse, mutect2, varscan2
- OPN1SW | c.204C>A p.P68= | Silent (SNP) | VAF 15/120 reads (13%) | called by muse, mutect2, varscan2
- OR14A16 | c.111G>A p.L37= | Silent (SNP) | VAF 18/85 reads (21%) | catalogued as COSV62926524; called by muse, mutect2, varscan2
- OR1S1 | c.759T>C p.T253= | Silent (SNP) | VAF 6/44 reads (14%) | catalogued as rs1285070998; called by muse, mutect2, varscan2
- OR2T12 | c.624C>A p.P208= | Silent (SNP) | VAF 14/60 reads (23%) | catalogued as COSV58776949, COSV58777448; called by muse, mutect2, varscan2
- OR5A1 | c.369C>T p.Y123= | Silent (SNP) | VAF 120/541 reads (22%) | catalogued as rs139346783; called by muse, mutect2, varscan2
- PAK6 | c.1821G>A p.V607= | Silent (SNP) | VAF 8/13 reads (62%) | catalogued as rs754628888; called by muse, mutect2, varscan2
- PCDHA12 | c.669A>G p.T223= | Silent (SNP) | VAF 10/53 reads (19%) | called by muse, mutect2, varscan2
- PDGFD | c.582C>T p.S194= | Silent (SNP) | VAF 6/27 reads (22%) | catalogued as rs1430826351; called by muse, mutect2, varscan2
- PIK3C2B | c.1665C>T p.L555= | Silent (SNP) | VAF 8/43 reads (19%) | called by muse, mutect2, varscan2
- PNCK | c.465C>A p.V155= (on ENST00000340888 / NM_001366975.1; = p.V238= on NM_001039582.3) | Silent (SNP) | VAF 16/117 reads (14%) | catalogued as COSV61743347; called by muse, mutect2, varscan2
- RTTN | c.2571G>T p.V857= | Silent (SNP) | VAF 14/86 reads (16%) | catalogued as rs1157667588; called by muse, mutect2
- RUBCN | c.2784C>T p.S928= | Silent (SNP) | VAF 9/59 reads (15%) | called by muse, mutect2
- SALL1 | c.3586C>A p.R1196= | Silent (SNP) | VAF 11/40 reads (28%) | called by muse, mutect2, varscan2
- SIPA1L1 | c.1839A>T p.V613= | Silent (SNP) | VAF 31/372 reads (8%) | catalogued as COSV62171906; called by muse, mutect2
- SLC17A3 | c.813G>T p.V271= | Silent (SNP) | VAF 19/88 reads (22%) | called by muse, mutect2, varscan2
- SLC47A1 | c.234C>A p.I78= | Silent (SNP) | VAF 11/41 reads (27%) | catalogued as rs760362357, COSV54504593; called by muse, mutect2, varscan2
- SPATA31A1 | c.3501C>T p.I1167= | Silent (SNP) | VAF 25/220 reads (11%) | called by muse, mutect2, varscan2
- SRRM4 | c.531C>A p.P177= | Silent (SNP) | VAF 12/54 reads (22%) | catalogued as COSV57416659; called by muse, mutect2, varscan2
- ST8SIA6 | c.966C>A p.S322= | Silent (SNP) | VAF 58/214 reads (27%) | called by muse, mutect2, varscan2
- STK39 | c.1110A>T p.S370= | Silent (SNP) | VAF 35/191 reads (18%) | called by muse, mutect2, varscan2
- SYNE1 | c.123G>T p.L41= | Silent (SNP) | VAF 19/84 reads (23%) | called by muse, mutect2, varscan2
- TBX20 | c.1311C>T p.R437= | Silent (SNP) | VAF 15/29 reads (52%) | catalogued as rs1338200376; called by muse, mutect2, varscan2
- TDRKH | c.1353G>T p.L451= | Silent (SNP) | VAF 11/121 reads (9%) | called by muse, mutect2
- TENT5D | c.546C>A p.P182= | Silent (SNP) | VAF 29/105 reads (28%) | catalogued as COSV100382624; called by muse, mutect2, varscan2
- THADA | c.3504A>T p.I1168= | Silent (SNP) | VAF 16/93 reads (17%) | catalogued as COSV57682708; called by muse, mutect2, varscan2
- TRERF1 | c.1395G>T p.G465= | Silent (SNP) | VAF 13/65 reads (20%) | called by muse, mutect2, varscan2
- TRERF1 | c.672G>T p.G224= | Silent (SNP) | VAF 41/122 reads (34%) | called by muse, mutect2, varscan2
- TSHZ3 | c.2298G>A p.P766= | Silent (SNP) | VAF 40/83 reads (48%) | catalogued as rs368908849, COSV53672099; called by muse, mutect2, varscan2
- TTN | c.40326G>A p.R13442= (on ENST00000591111; = p.R6018= on NM_003319.4) | Silent (SNP) | VAF 6/69 reads (9%) | called by muse, mutect2
- ZNF462 | c.5172G>T p.A1724= | Silent (SNP) | VAF 18/69 reads (26%) | called by muse, mutect2, varscan2
- ALMS1P1 | chr2:73701129 G>T | 3'Flank (SNP) | VAF 13/77 reads (17%) | called by muse, mutect2, varscan2
- ANXA13 | c.15+1450C>G | Intron (SNP) | VAF 31/87 reads (36%) | called by muse, mutect2, varscan2
- CMKLR1 | c.*2C>A | 3'UTR (SNP) | VAF 35/138 reads (25%) | catalogued as COSV56436615; called by muse, mutect2, varscan2
- DCHS2 | n.1097C>A | RNA (SNP) | VAF 20/86 reads (23%) | called by muse, mutect2, varscan2
- DUSP13 | c.*294A>T | 3'UTR (SNP) | VAF 6/68 reads (9%) | called by muse, mutect2
- MACF1 | c.15832-9762A>G | Intron (SNP) | VAF 27/139 reads (19%) | called by muse, mutect2, varscan2
- OFCC1 | n.161G>T | RNA (SNP) | VAF 97/317 reads (31%) | catalogued as rs1315535637; called by muse, mutect2, varscan2
- SNORD52 | n.24G>A | RNA (SNP) | VAF 10/68 reads (15%) | called by muse, mutect2, varscan2
